CPTAC case C3L-06413 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a454982a-9820-4b52-bb42-7698f5bb121f

Demographics
Sex at birth: male; Race: white; Year of birth: 1935; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Body of stomach; Age at diagnosis: 84.1 years (30,703 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic stage: Stage IA; Tumor grade: G1; Residual disease: RX; Days to last known disease status: 257 days; Days to last follow up: 257 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 2.

Follow-up (1 entry)
- Days to follow up: 257 days; Disease response: Complete Response; Karnofsky performance status: 80; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06413-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 450 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-06413-22: Section location: Body; Percent tumor nuclei: 60; Percent necrosis: 0.
- Sample C3L-06413-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 520 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-06413-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
